Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7292, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7292-01A (Primary Tumor).

[page 1 of 3]
PATHOLOGICAL DIAGNOSIS:

BRAIN, LEFT TEMPORAL LOBE, BIOPSY: ASTROCYTOMA, ANAPLASTIC.

Operation/Specimen: Brain, left temporal lobe.

Clinical History and Pre-Op Dx: None given.

GROSS PATHOLOGY: One container labeled with the patient's MRN and name and including 3 small fragments of grayish white semifirm tissue. After taking a small sample for the Intraoperative Consultation, the entire specimen is submitted in cassettes 1 and 2.

INTRAOPERATIVE CONSULTATION: Glioma, anaplastic. [REDACTED]

MICROSCOPIC: Three fragments of cerebral cortex showing similar appearance. The normal architecture of the cortex is effaced by an infiltrating neoplasm composed of medium sized cells, many of which have abundant eosinophilic cytoplasm and elongated thin processes. Nuclear pleomorphism and occasional atypical mitoses are present. Many of the blood vessels show hypertrophy of the endothelial lining. Areas of coagulation necrosis are not visible but there are scattered recent and small hemorrhages. A few multinucleated cells are scattered throughout this specimen. Mineral salt deposits are not visible.

COMMENT: The specimen was received in the afternoon of [REDACTED]

Histology slides are available for reading today, [REDACTED]
[REDACTED]
[REDACTED]
[REDACTED]

ADDENDUM REPORT

PATHOLOGICAL DIAGNOSIS:

A. BRAIN, LEFT TEMPORAL LOBE, EXCISION: ANAPLASTIC ASTROCYTOMA.

[page 2 of 3]
- B. BRAIN, LEFT TEMPORAL UNCUS, EXCISION: ANAPLASTIC ASTROCYTOMA.
C. BRAIN, LEFT PARAHIPPOCAMPUS, EXCISION: ANAPLASTIC ASTROCYTOMA.
D. BRAIN, LEFT HIPPOCAMPUS, EXCISION: ANAPLASTIC ASTROCYTOMA. MIB-

1

LABELLING INDEX 15%.

SEE MICROSCOPIC DESCRIPTION AND COMMENT.

Operation/Specimen: A. Left temporal lobe, B. Left temporal uncus, C. Left parahippocampus, D. Left hippocampus.

Clinical History and Pre-Op Dx: None given.

GROSS DESCRIPTION:

A. "Left temporal lobe", discoid portion of cerebral cortex and white matter, 4.5 x 4 x 1.5 cm, semifirm. Submitted in total, 1-13.

B. "Left temporal uncus", four fragments, aggregating to 1 x 1 x 0.3 cm. Semifirm, tanish-white. In total, 14.

C. "Left parahippocampus", one fragment, 1 x 0.7 x 0.3 cm. Tanish-white. In total, 15.

D. "Left hippocampus", five fragments, aggregating to 3 x 2.2 x 0.9 cm. Semifirm, tanish-white. In total, 16-19.

MICROSCOPIC: A. Portions of cerebral cortex and adjacent white matter

which are focally extensively infiltrated by a neoplastic proliferation

of glial cells. The neoplastic cells have rather small nuclei with moderate nuclear pleomorphism, and diffusely permeate the white matter and cortex with prominent perineuronal satellitosis and focal subpial accumulation. Mitotic figures are occasionally seen, however, microvascular cellular proliferation or necrosis is absent.

B. Fragments of brain tissue extensively infiltrated by a neoplasm similar to that described for part A. The cellularity is higher and the nuclear pleomorphism is more prominent in this specimen, and mitotic figures are also observed. Again, microvascular cellular proliferation and necrosis are absent.

C. Portions of brain tissue extensively infiltrated by a neoplasm similar to that described for part A.

D. Portions of hippocampus which are focally infiltrated by a neoplasia similar to that described for part B, which is effacing the dentate gyrus and pyramidal cell layer.

SPECIAL STAINS: MIB-1 and factor VIII AA immunoperoxidase methods were preformed on blocks 5 and 14.

With the MIB-1, a labelling index of about 15% was determined on section 14 in areas of solid tumor. With the FVIII AA, no endothelial

[page 3 of 3]
microvascular proliferation was demonstrated.

COMMENT: In all the four specimens, there is extensive infiltration of

the gray and white matter by a fibrillary astrocytoma. The tumor effaces the normal cortical architecture with the presence of prominent

satellitosis and focal subpial accumulation. The neurons present throughout the specimens are considered to be native entrapped neurons,

not part of the neoplasm. The tumor is moderately cellular with moderate nuclear pleomorphism, and is not difficult to find mitotic figures. However, microvascular cellular proliferation and necrosis are absent. The cellularity, degree of nuclear atypia and presence of mitoses with a high MIB-1 labelling index of 15%, justify a diagnosis of anaplastic astrocytoma. The absence of endothelial proliferation, however, probably places this neoplasm at the low end of the spectrum of anaplastic astrocytomas.

[REDACTED]

TISSUE COMMITTEE CODE: TC1.

BILLING CODES [REDACTED]

Source: NCI Genomic Data Commons file 4738f152-8bec-4c8b-8b5d-0d7de634148f (TCGA-DU-7292.13D45E58-4EB6-405E-916F-36BEC44D23E2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).